Somatic mutation profile of tumor specimen TCGA-RX-A8JQ-01A (aliquot TCGA-RX-A8JQ-01A-11D-A35D-08) from TCGA case TCGA-RX-A8JQ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 44.3 years (16,182 days).
Specimen TCGA-RX-A8JQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75db0593-0cd0-448c-af79-d4d23b2d1aaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RX-A8JQ-10A (Blood Derived Normal), aliquot TCGA-RX-A8JQ-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3533404-1412-4e66-adf4-4a3bcf5cfa2e

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/129 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- B4GALNT4 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750624114, COSV100327260; called by muse, mutect2, varscan2
- IKZF3 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as rs1423135227; called by muse, mutect2
- DNAH7 | c.6504G>C p.L2168F | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRUNE2 | c.2238G>C p.E746D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2
- TRMT1L | c.1249T>C p.Y417H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALOX15B | c.969C>T p.C323= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs367774742; called by muse, mutect2, varscan2
